Somatic mutation profile of tumor specimen 0DSS5R from CCDI case PBCIKU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Nasopharynx, NOS; Age at diagnosis: 6.3 years (2,299 days).
Specimen 0DSS5R: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c5c37fec-e90b-47e1-874f-ba6185a0254d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSS6B (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad26dbdf-552b-47ed-9159-e86cde78087d

The open-access MAF lists 64 somatic variants for this specimen: 37 protein-altering or splice-affecting, 12 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 12, 5'UTR 6, Intron 6, 3'UTR 3, Nonsense Mutation 2, Frame Shift Del 2, Splice Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.376-1G>T p.X126_splice | Splice Site (SNP) | VAF 153/188 reads (81%) | hotspot (GDC flag); catalogued as CS1313555, COSV52688618, COSV52749979, COSV52994579, COSV52996344; called by muse, mutect2, varscan2
- ARHGEF4 | c.1774G>C p.E592Q | Missense Mutation (SNP) | VAF 213/655 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.674); catalogued as rs370443864, COSV58128602; called by muse, mutect2, varscan2
- FCN1 | c.61C>T p.H21Y | Missense Mutation (SNP) | VAF 168/221 reads (76%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs1243539460, COSV100878978; called by muse, mutect2
- HECTD2 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 165/425 reads (39%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.01); catalogued as rs755956224; called by muse, mutect2, varscan2
- HOXD8 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 22/559 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57486367; called by muse, mutect2
- ITGAX | c.2627T>A p.I876N | Missense Mutation (SNP) | VAF 149/355 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.289); catalogued as rs747723994; called by muse, mutect2, varscan2
- MEGF8 | c.3175C>T p.L1059F (on ENST00000251268 / NM_001271938.2; = p.L992F on NM_001410.3) | Missense Mutation (SNP) | VAF 74/240 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as rs1486044137; called by muse, mutect2, varscan2
- MMP12 | c.29A>G p.Q10R | Missense Mutation (SNP) | VAF 74/441 reads (17%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.462); catalogued as rs201787630; called by muse, mutect2, varscan2
- MUC6 | c.5300C>A p.T1767N | Missense Mutation (SNP) | VAF 66/482 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); catalogued as rs765930733; called by muse, mutect2, varscan2
- OR6N1 | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 18/500 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100625080, COSV58648903; called by muse, mutect2
- RALGAPA1 | c.2947A>G p.I983V | Missense Mutation (SNP) | VAF 129/287 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764582132; called by muse, mutect2, varscan2
- RIMS2 | c.2945G>A p.R982Q (on ENST00000666250 / NM_001348490.2; = p.R790Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 109/786 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as rs747545747, COSV51668880; called by muse, mutect2, varscan2
- SHPK | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 182/213 reads (85%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as rs769295443; called by muse, mutect2, varscan2
- ST14 | c.2450G>T p.R817L | Missense Mutation (SNP) | VAF 332/1124 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53831880; called by muse, mutect2, varscan2
- STRIP1 | c.1946C>T p.A649V | Missense Mutation (SNP) | VAF 26/484 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.21); catalogued as COSV63930386; called by muse, mutect2
- SYT6 | c.1086G>C p.L362F (on ENST00000610222 / NM_001366225.1; = p.L277F on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/600 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101059747; called by muse, mutect2
- TRPM3 | c.3607A>G p.I1203V (on ENST00000357533 / NM_001366142.2; = p.I1058V on NM_020952.6) | Missense Mutation (SNP) | VAF 177/409 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1480616257; called by muse, mutect2, varscan2
- ADGRB3 | c.593del p.C198Sfs*15 | Frame Shift Del (DEL) | VAF 135/388 reads (35%) | called by mutect2, pindel, varscan2
- COL15A1 | c.244C>G p.L82V | Missense Mutation (SNP) | VAF 340/756 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- CREBBP | c.2894C>T p.A965V | Missense Mutation (SNP) | VAF 20/434 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- EPHA1 | c.2719C>G p.L907V | Missense Mutation (SNP) | VAF 134/347 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- GOLGA8H | c.1726C>A p.L576I | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2
- HLA-G | c.118G>T p.G40C | Missense Mutation (SNP) | VAF 224/457 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- IQUB | c.1745C>A p.A582E | Missense Mutation (SNP) | VAF 99/243 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- KDR | c.3827C>G p.T1276S | Missense Mutation (SNP) | VAF 155/391 reads (40%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP4 | c.2126G>T p.C709F | Missense Mutation (SNP) | VAF 79/393 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MARK4 | c.698_700dup p.D233dup | In Frame Ins (INS) | VAF 138/515 reads (27%) | called by mutect2, pindel, varscan2
- MYO16 | c.3716G>A p.R1239K | Missense Mutation (SNP) | VAF 119/137 reads (87%) | SIFT deleterious (0.04); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- NIPBL | c.2984T>C p.L995P | Missense Mutation (SNP) | VAF 190/600 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- OR2D2 | c.282C>A p.F94L | Missense Mutation (SNP) | VAF 186/878 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PDGFRA | c.61_62delinsG p.I21Afs*21 | Frame Shift Del (DEL) | VAF 187/705 reads (27%) | called by pindel, varscan2*
- POU6F2 | c.1565T>C p.I522T | Missense Mutation (SNP) | VAF 14/462 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- RBPJ | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 173/479 reads (36%) | called by muse, mutect2, varscan2
- RECK | c.1546G>T p.D516Y | Missense Mutation (SNP) | VAF 186/422 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- SLC8A3 | c.1483G>T p.E495* | Nonsense Mutation (SNP) | VAF 118/264 reads (45%) | called by muse, mutect2, varscan2
- SP7 | c.946C>G p.R316G | Missense Mutation (SNP) | VAF 87/298 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM182 | c.555G>T p.M185I | Missense Mutation (SNP) | VAF 176/612 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ARFGEF3 | c.6117C>T p.S2039= | Silent (SNP) | VAF 190/554 reads (34%) | catalogued as rs776008501, COSV52472287; called by muse, mutect2, varscan2
- C3orf85 | c.132C>T p.Y44= | Silent (SNP) | VAF 152/566 reads (27%) | called by muse, mutect2, varscan2
- CFAP61 | c.1302C>A p.I434= | Silent (SNP) | VAF 72/665 reads (11%) | called by muse, mutect2, varscan2
- CFAP92 | c.1492C>T p.L498= | Silent (SNP) | VAF 41/438 reads (9%) | called by muse, mutect2, varscan2
- CTTNBP2 | c.240A>G p.L80= | Silent (SNP) | VAF 160/360 reads (44%) | called by muse, mutect2, varscan2
- ENG | c.1587C>G p.R529= | Silent (SNP) | VAF 100/144 reads (69%) | catalogued as CX104975; called by muse, mutect2, varscan2
- FUT10 | c.171G>A p.T57= | Silent (SNP) | VAF 121/1090 reads (11%) | catalogued as rs376616754; called by muse, mutect2, varscan2
- IRS1 | c.1041G>C p.V347= | Silent (SNP) | VAF 102/550 reads (19%) | called by muse, mutect2, varscan2
- MYH11 | c.1833C>T p.S611= | Silent (SNP) | VAF 177/468 reads (38%) | catalogued as rs990109247, COSV55569605; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYOM3 | c.4251G>A p.T1417= | Silent (SNP) | VAF 141/387 reads (36%) | catalogued as rs567009702; called by muse, mutect2, varscan2
- RPL5 | c.234G>C p.A78= | Silent (SNP) | VAF 91/224 reads (41%) | catalogued as rs778200458, COSV59874071; called by muse, mutect2, varscan2
- ZNF423 | c.2469C>A p.A823= (on ENST00000563137 / NM_001379286.1; = p.A815= on NM_015069.4) | Silent (SNP) | VAF 199/485 reads (41%) | called by muse, mutect2, varscan2
- BIN3 | c.338+87G>T | Intron (SNP) | VAF 38/233 reads (16%) | called by muse, mutect2, varscan2
- CENPH | c.-5C>A | 5'UTR (SNP) | VAF 24/270 reads (9%) | called by muse, mutect2
- DOCK2 | c.*98C>A | 3'UTR (SNP) | VAF 48/142 reads (34%) | called by muse, mutect2, varscan2
- EPHB4 | c.53-38C>T | Intron (SNP) | VAF 106/202 reads (52%) | catalogued as rs370177529; called by muse, mutect2, varscan2
- EYS | c.1767-7307C>A | Intron (SNP) | VAF 341/770 reads (44%) | catalogued as COSV101005134; called by muse, mutect2, varscan2
- FOXL2NB | c.-45G>A | 5'UTR (SNP) | VAF 43/157 reads (27%) | called by muse, mutect2, varscan2
- KEL | c.-57C>T | 5'UTR (SNP) | VAF 152/334 reads (46%) | catalogued as rs563094452, COSV62333805, COSV62338606; called by muse, mutect2, varscan2
- LAPTM4A | c.-3A>G | 5'UTR (SNP) | VAF 16/195 reads (8%) | catalogued as rs377542525; called by muse, mutect2
- LINC02054 | n.2595-11449T>C | Intron (SNP) | VAF 90/445 reads (20%) | called by muse, mutect2, varscan2
- PSG7 | c.-9G>C | 5'UTR (SNP) | VAF 75/295 reads (25%) | called by muse, mutect2, varscan2
- SLC18A3 | c.*60G>A | 3'UTR (SNP) | VAF 21/52 reads (40%) | called by muse, mutect2
- SYCE1 | c.272-9G>A | Intron (SNP) | VAF 150/394 reads (38%) | called by muse, mutect2, varscan2
- TRHDE | c.*53G>A | 3'UTR (SNP) | VAF 42/149 reads (28%) | catalogued as rs1008981044, COSV99669205, COSV99669689; called by muse, mutect2, varscan2
- TRIM38 | c.-9A>G | 5'UTR (SNP) | VAF 63/155 reads (41%) | catalogued as rs1184612722; called by muse, mutect2, varscan2
- VEGFA | c.546-83T>C | Intron (SNP) | VAF 5/76 reads (7%) | called by muse, mutect2
